Somatic mutation profile of tumor specimen TCGA-32-2632-01A (aliquot TCGA-32-2632-01A-01D-1495-08) from TCGA case TCGA-32-2632, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.2 years (29,281 days).
Specimen TCGA-32-2632-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a79847e-bccf-4b79-83f0-d17f78f6ef80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2632-10A (Blood Derived Normal), aliquot TCGA-32-2632-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5971903c-b88a-4848-bd4a-47ed0347e8a3

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 18, Nonsense Mutation 4, Frame Shift Ins 2, RNA 2, Intron 1, Splice Site 1, 3'UTR 1, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 4293/4490 reads (96%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, varscan2
- RB1 | c.1024del p.T342Lfs*7 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | catalogued as rs587778844, CM144108, COSV99927802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA9 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as COSV60629747; called by muse, mutect2, varscan2
- ABCB5 | c.2377G>A p.G793S (on ENST00000404938 / NM_001163941.2; = p.G348S on NM_178559.6) | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV51718271; called by muse, mutect2, varscan2
- ABCD3 | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64644218; called by muse, mutect2, varscan2
- AC004593.2 | c.1082A>C p.H361P | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56099721; called by muse, mutect2, varscan2
- ACY3 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs928379429, COSV54830001; called by muse, mutect2, varscan2
- ADAM32 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as rs757189886, COSV65948045; called by muse, mutect2, varscan2
- ANO9 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs775078390, COSV60449760; called by muse, mutect2, varscan2
- AQP9 | c.217T>A p.Y73N | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99582960; called by muse, mutect2, varscan2
- ARHGAP45 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57429077; called by muse, mutect2, varscan2
- ASPM | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54136561; called by muse, mutect2, varscan2
- CABYR | c.216A>T p.E72D | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV59112319; called by muse, mutect2, varscan2
- CALN1 | c.503C>T p.S168L (on ENST00000329008 / NM_001017440.3; = p.S210L on NM_031468.4) | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs143545775; called by muse, mutect2, varscan2
- CCL14 | c.136C>T p.R46C (on ENST00000618404 / NM_032963.4; = p.R62C on NM_032962.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs372808751; called by muse, mutect2, varscan2
- CENPE | c.7030A>G p.K2344E | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.681); catalogued as COSV54388031; called by muse, mutect2, varscan2
- CFAP20DC | c.748C>T p.R250W (on ENST00000482387 / NM_001351530.2; = p.R125W on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs756677660, COSV55925989; called by muse, mutect2, varscan2
- CIP2A | c.1827+1G>A p.X609_splice | Splice Site (SNP) | VAF 76/268 reads (28%) | catalogued as COSV55420745; called by muse, mutect2, varscan2
- CLYBL | c.219C>G p.D73E | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV59227179; called by muse, mutect2, varscan2
- CNTNAP5 | c.2540A>G p.E847G | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1294640842, COSV70506926; called by muse, varscan2
- COL6A5 | c.6709A>T p.S2237C (on ENST00000312481; = p.S2233C on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV55213228; called by muse, mutect2, varscan2
- CYP4F22 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs146265982, COSV54106998; called by muse, mutect2, varscan2
- DCSTAMP | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV52579577; called by muse, mutect2, varscan2
- DDX4 | c.1020G>A p.A340= | Splice Region (SNP) | VAF 55/215 reads (26%) | catalogued as COSV61756758; called by muse, mutect2, varscan2
- DOCK5 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52396789; called by muse, mutect2
- DOCK5 | c.1939T>A p.S647T | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52409127; called by muse, mutect2, varscan2
- EFCAB6 | c.3917C>T p.P1306L | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1292409726, COSV53070442; called by muse, mutect2, varscan2
- F5 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV63127222; called by muse, mutect2
- FAM81B | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.275); catalogued as COSV51986151; called by muse, mutect2, varscan2
- FLG | c.6470C>T p.S2157L | Missense Mutation (SNP) | VAF 300/854 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs761306814, COSV64237796; called by muse, mutect2, varscan2
- GABRA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 109/282 reads (39%) | catalogued as COSV50115651; called by muse, mutect2, varscan2
- GCC1 | c.2227C>G p.L743V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58463556; called by muse, mutect2, varscan2
- GRIN2A | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1489261681, COSV58032859, COSV58037182; ClinVar: not provided; called by muse, mutect2, varscan2
- HDAC2 | c.1171C>G p.H391D | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64039265; called by muse, mutect2, varscan2
- HYDIN | c.13792G>A p.V4598M | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV66641615; called by muse, mutect2, varscan2
- IGKV3D-11 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1311393754; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1998C>A p.H666Q | Missense Mutation (SNP) | VAF 96/133 reads (72%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV61175953; called by muse, mutect2, varscan2
- ING2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56564128; called by muse, mutect2, varscan2
- LILRB1 | c.1825C>A p.Q609K (on ENST00000427581; = p.Q558K on NM_006669.6) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV61121060; called by muse, mutect2, varscan2
- LTBP2 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs551341275, COSV56205068; called by muse, mutect2, varscan2
- LTN1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375416726; called by muse, mutect2, varscan2
- MCHR2 | c.304G>T p.G102W | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56007388, COSV99912382; called by muse, mutect2, varscan2
- MGAM | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 127/549 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1554466069, COSV101527763, COSV72075408; called by muse, mutect2, varscan2
- MYH7 | c.5729C>T p.A1910V | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1454105335, COSV62522799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDN | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV59361139; called by muse, mutect2, varscan2
- NIPAL4 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV61729938, COSV61730965; called by muse, mutect2, varscan2
- NLRP7 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs375095148, COSV60177723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH2 | c.5123C>G p.S1708C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV56687314, COSV56702208; called by muse, mutect2, varscan2
- NRXN3 | c.2026G>C p.G676R (on ENST00000335750 / NM_001330195.2; = p.G303R on NM_004796.6) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV59795755; called by muse, mutect2, varscan2
- NUP214 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | catalogued as rs1427146168, COSV63912364; called by muse, mutect2, varscan2
- OR6M1 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368975645; called by muse, mutect2, varscan2
- PIK3CG | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1462539802, COSV63248803; called by muse, mutect2
- PIK3CG | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV63252250; called by muse, mutect2, varscan2
- PNPLA5 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV53376034; called by muse, mutect2
- QPCT | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.024); catalogued as COSV58120953; called by muse, mutect2, varscan2
- RAPGEF6 | c.77A>T p.N26I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV57253891; called by muse, mutect2, varscan2
- RDH8 | c.653C>T p.A218V (on ENST00000651512; = p.A198V on NM_015725.4) | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.355); catalogued as rs754093769, COSV50675550; called by muse, mutect2, varscan2
- RELT | c.303G>C p.W101C | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV50362432; called by muse, mutect2, varscan2
- SEMG1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs141417035, COSV54872621, COSV54873769; called by muse, mutect2, varscan2
- SLC5A7 | c.542T>A p.L181H | Missense Mutation (SNP) | VAF 122/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50889216; called by muse, mutect2, varscan2
- SPTA1 | c.4201C>G p.Q1401E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV100935056, COSV63757909; called by muse, mutect2, varscan2
- TDRD9 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 72/229 reads (31%) | catalogued as rs143367834; called by muse, mutect2, varscan2
- TRHDE | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs770977159, COSV53861169, COSV99670324; called by muse, mutect2
- TTC17 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as COSV50016250; called by muse, mutect2, varscan2
- TTN | c.58010A>G p.E19337G (on ENST00000591111; = p.E11913G on NM_003319.4) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | PolyPhen possibly damaging (0.737); catalogued as COSV60279141; called by muse, mutect2, varscan2
- ZNF599 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61397229; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626dup p.N209Kfs*2 | Frame Shift Ins (INS) | VAF 128/178 reads (72%) | called by mutect2, varscan2
- TBC1D23 | c.469dup p.I157Nfs*23 | Frame Shift Ins (INS) | VAF 38/129 reads (29%) | called by mutect2, pindel, varscan2
- UMODL1 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.15); called by muse, mutect2
- AP5Z1 | c.144C>T p.L48= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as rs1367619559, COSV62243277; called by muse, mutect2, varscan2
- ATP11A | c.1329C>T p.N443= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs760113692, COSV52120995; called by muse, mutect2, varscan2
- CCDC8 | c.1410G>A p.R470= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV100281926, COSV56774485; called by muse, mutect2, varscan2
- DMD | c.2964T>C p.S988= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV63783421; called by muse, mutect2, varscan2
- DOCK5 | c.5175C>T p.S1725= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs768511425, COSV52409137; called by muse, mutect2, varscan2
- GTPBP3 | c.1239G>A p.K413= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV61414664; called by muse, mutect2, varscan2
- JPH1 | c.768G>A p.T256= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as COSV60614037; called by muse, mutect2, varscan2
- KRT38 | c.144C>T p.N48= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as rs369697357; called by muse, mutect2, varscan2
- LSMEM2 | c.306C>T p.L102= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs116862338; called by muse, mutect2, varscan2
- MAP7 | c.1587G>A p.E529= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV63422339; called by muse, mutect2
- MEP1B | c.495G>A p.S165= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs759506843, COSV52498985; called by muse, mutect2, varscan2
- OR4X1 | c.327G>A p.E109= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV60723685; called by muse, mutect2, varscan2
- PHF20 | c.2559G>A p.Q853= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV64977341; called by muse, mutect2, varscan2
- PTK2B | c.2475G>A p.E825= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs766407905, COSV57752833; called by muse, mutect2, varscan2
- SCN7A | c.3267C>T p.D1089= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV69274085; called by muse, mutect2, varscan2
- SLC6A18 | c.1515G>A p.A505= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs202091732, COSV57251096; called by muse, mutect2, varscan2
- TNFRSF11A | c.219G>A p.P73= | Silent (SNP) | VAF 90/305 reads (30%) | catalogued as rs780909910, COSV54024687; called by muse, mutect2, varscan2
- TRMT44 | c.1935A>G p.L645= | Silent (SNP) | VAF 109/330 reads (33%) | catalogued as rs533799281, COSV67664746; called by muse, mutect2, varscan2
- LEKR1 | c.*1389C>T | 3'UTR (SNP) | VAF 60/189 reads (32%) | catalogued as COSV62960249; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397702 G>T | 3'Flank (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3402G>T | RNA (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- SSPOP | n.12676G>A | RNA (SNP) | VAF 14/71 reads (20%) | catalogued as rs368478065; called by muse, mutect2
- TTN | c.34354+583A>T | Intron (SNP) | VAF 34/136 reads (25%) | catalogued as COSV60279167; called by muse, mutect2, varscan2
